Somatic mutation profile of tumor specimen C3N-00199-02 (aliquot CPT0014260006) from CPTAC case C3N-00199, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 65.7 years (24,010 days).
Specimen C3N-00199-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c45d8b5-656d-4bec-8a57-44e524f93616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00199-31 (Blood Derived Normal), aliquot CPT0015050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/427e1a70-219c-4266-b7d4-d00c72617f68

The open-access MAF lists 317 somatic variants for this specimen: 206 protein-altering or splice-affecting, 72 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 72, Intron 18, Nonsense Mutation 10, RNA 8, 5'UTR 7, Frame Shift Del 5, Splice Site 5, 3'UTR 4, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 461/856 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 116/334 reads (35%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AKR1B15 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310674609, COSV71152087; called by muse, mutect2
- ARPP21 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV51791844; called by muse, mutect2, varscan2
- ATP7B | c.3589G>A p.A1197T | Missense Mutation (SNP) | VAF 64/598 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758025913, CM994114, COSV54441279; ClinVar: uncertain significance; called by muse, mutect2
- BATF3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV54658141; called by muse, mutect2
- BCL2L10 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750162170; called by muse, mutect2, varscan2
- CACNA1F | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 213/350 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV100544728; called by muse, mutect2, varscan2
- CACTIN | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 215/475 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.387); catalogued as rs773244712; called by muse, mutect2, varscan2
- CBX6 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV53321453; called by muse, mutect2
- CCDC168 | c.14032G>T p.E4678* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100487663; called by muse, mutect2, varscan2
- CCDC88B | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs949145463, COSV57268633; called by muse, mutect2, varscan2
- CHRND | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766740341, COSV51319354; called by muse, mutect2
- CHST1 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1564995568; called by muse, mutect2, varscan2
- CNGA2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747754116, COSV61704268, COSV61704381; called by muse, mutect2
- CNTROB | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 35/382 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.553); catalogued as rs1464038566; called by muse, mutect2
- COL27A1 | c.3134G>T p.G1045V | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100621031; called by muse, mutect2
- CUBN | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 62/139 reads (45%) | catalogued as COSV64715118; called by muse, mutect2, varscan2
- CYB5R2 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs146956666; called by muse, mutect2, varscan2
- DBH | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 147/451 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs1428988947; called by muse, mutect2, varscan2
- ECE1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 147/554 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99941958; called by muse, mutect2, varscan2
- EMCN | c.638A>T p.Y213F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56457541; called by muse, mutect2
- FAT3 | c.7774G>C p.D2592H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53149181, COSV53150702; called by muse, mutect2, varscan2
- FMN1 | c.2413G>T p.V805F (on ENST00000616417 / NM_001277313.2; = p.V582F on NM_001103184.4) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV57926901; called by muse, mutect2, varscan2
- GFRAL | c.22+1G>A p.X8_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as COSV61236871; called by muse, mutect2, varscan2
- HCLS1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs559028635, COSV57525646; called by muse, mutect2, varscan2
- IFNA6 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1181102432, COSV66506695; called by muse, mutect2
- IHH | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV55393825; called by muse, mutect2, varscan2
- KANSL1L | c.2932C>G p.L978V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs747592516; called by muse, varscan2
- KDM4A | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1301506786, COSV64958861; called by muse, mutect2, varscan2
- KLHL4 | c.1657G>T p.V553L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs755871530, COSV64141313; called by muse, mutect2, varscan2
- L1TD1 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63133475; called by muse, mutect2, varscan2
- LRCH3 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs768172764; called by muse, mutect2, varscan2
- LRFN5 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985010; called by muse, mutect2, varscan2
- LRFN5 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53246439; called by muse, mutect2, varscan2
- LYST | c.8600A>T p.N2867I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV67703275; called by muse, mutect2, varscan2
- MAGEA6 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs141271077, COSV61449559; called by muse, mutect2, varscan2
- MARVELD3 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1366350085; called by muse, mutect2, varscan2
- MKI67 | c.1729G>A p.V577I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.055); catalogued as rs1167658826, COSV64077502; called by mutect2, varscan2
- MMP16 | c.1061G>C p.R354P | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164626; called by muse, mutect2, varscan2
- MYH7B | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 23/385 reads (6%) | catalogued as COSV53422992; called by muse, mutect2
- MYH8 | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV101238414; called by muse, mutect2, varscan2
- NCKAP5L | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258449; called by muse, mutect2, varscan2
- NYNRIN | c.3575C>T p.P1192L | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as rs751558441; called by muse, mutect2, varscan2
- OR2L2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV63558414; called by muse, mutect2, varscan2
- OR2T1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 45/204 reads (22%) | catalogued as rs1296415026, COSV63541934; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 56/237 reads (24%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OTOG | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1037786055, COSV61130959; called by muse, mutect2
- OTUD7B | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs782658838; called by muse, mutect2, varscan2
- PCDHA10 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 82/682 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs773891459, COSV56516274; called by muse, mutect2, varscan2
- PCDHB6 | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554277529, COSV99170025; called by muse, mutect2, varscan2
- PCDHGA4 | c.1619C>A p.S540Y | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV53935776; called by muse, mutect2, varscan2
- PDE11A | c.2753C>A p.A918D | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.035); catalogued as COSV53706652; called by muse, mutect2, varscan2
- PKP1 | c.849C>A p.V283= | Splice Region (SNP) | VAF 102/871 reads (12%) | catalogued as COSV55820670; called by muse, mutect2, varscan2
- PKP2 | c.1631C>A p.P544Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50756424; called by muse, mutect2, varscan2
- PKP3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs767775391; called by muse, mutect2
- PLCD4 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 97/418 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs998141297, COSV68842677; called by muse, mutect2, varscan2
- PLD5 | c.505C>A p.L169I (on ENST00000442594; = p.L107I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as COSV59157531; called by muse, mutect2, varscan2
- RASAL2 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs766767770; called by muse, mutect2, varscan2
- RD3 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100879257; called by muse, mutect2, varscan2
- RELN | c.8120T>A p.V2707E | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59035971; called by muse, mutect2, varscan2
- RGPD3 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 54/471 reads (11%) | catalogued as rs753903388, COSV100449642, COSV58739140; called by muse, mutect2, varscan2
- RP1L1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 36/630 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200724846; ClinVar: likely benign; called by muse, mutect2
- RYR2 | c.2783A>T p.E928V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1460208396; called by muse, mutect2, varscan2
- SCART1 | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62987131; called by muse, varscan2
- SIDT1 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs774292168, COSV53504412; called by muse, mutect2, varscan2
- SPATA31A1 | c.3655G>T p.E1219* | Nonsense Mutation (SNP) | VAF 49/847 reads (6%) | catalogued as rs1478444130; called by muse, mutect2
- STYXL2 | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54802860; called by muse, mutect2, varscan2
- TENM2 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 199/583 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen probably damaging (0.982); catalogued as COSV72854927; called by muse, mutect2, varscan2
- TMEM132E | c.1329G>T p.W443C (on ENST00000321639; = p.W533C on NM_001304438.2) | Missense Mutation (SNP) | VAF 50/575 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395878; called by muse, mutect2
- TRAF3IP3 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV50559305, COSV99161778; called by muse, mutect2, varscan2
- TRPM1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1355796117, COSV56634624, COSV56636990; called by muse, mutect2, varscan2
- UNC45B | c.2683C>A p.L895M | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV52095982; called by muse, mutect2, varscan2
- VAPB | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99668541; called by muse, mutect2, varscan2
- XIRP2 | c.1777A>G p.R593G (on ENST00000628543; = p.R768G on NM_152381.6) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54740991, COSV99737409; called by muse, mutect2, varscan2
- ZNF423 | c.2665G>A p.A889T (on ENST00000563137 / NM_001379286.1; = p.A881T on NM_015069.4) | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.062); catalogued as rs373166241; ClinVar: uncertain significance; called by muse, mutect2
- ZNF831 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV64037143; called by muse, mutect2
- ADAMTS2 | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 142/448 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ADAMTS6 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCK5 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.1995G>T p.Q665H (on ENST00000506720 / NM_001322402.2; = p.Q597H on NM_015236.6) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2
- AGT | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ALG1L | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AMER3 | c.2422C>A p.H808N | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BTBD18 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- C4orf54 | c.4064G>T p.R1355M | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CAPZA3 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CASP1 | c.532A>T p.R178* (on ENST00000436863 / NM_033292.4; = p.R157* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- CCDC96 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CD19 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 111/598 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CD84 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, varscan2
- CECR2 | c.2729A>T p.Q910L (on ENST00000342247 / NM_001290047.2; = p.Q727L on NM_001290046.1) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- CHD1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CHRNB2 | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 232/982 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCA2 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- COG5 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- COL8A2 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 102/535 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CUL9 | c.4910T>G p.L1637R | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP27C1 | c.63A>C p.E21D | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF12L1 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 145/173 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAF8L2 | c.1487T>C p.F496S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- DENND4B | c.3818G>T p.R1273L | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DENND4C | c.3115G>T p.G1039C (on ENST00000434457 / NM_001330640.2; = p.G990C on NM_017925.7) | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DLGAP2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP3 | c.1346G>T p.S449I | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAJC6 | c.2171A>T p.Q724L | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DSPP | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.028); called by muse, mutect2
- EHMT1 | c.3251A>T p.Y1084F | Missense Mutation (SNP) | VAF 52/571 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELFN1 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERCC3 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- ERN1 | c.2327del p.G776Afs*33 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- FAM166C | c.447_448insG p.L150Afs*49 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | called by mutect2, pindel
- FAM83B | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FGD1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FLYWCH1 | c.649G>C p.E217Q (on ENST00000253928 / NM_001308068.2; = p.E216Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FOXJ2 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXN2 | c.298T>A p.C100S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FREM1 | c.4670T>A p.L1557Q | Missense Mutation (SNP) | VAF 254/471 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GABRA1 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GABRA6 | c.321G>C p.M107I | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GALNT3 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- GDF10 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.023); called by muse, mutect2
- GJA8 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 211/571 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GNB4 | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GUCY1A1 | c.376+1G>T p.X126_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | called by muse, varscan2
- H3-3A | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- HOXA2 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 197/570 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IQSEC2 | c.2399G>T p.R800L (on ENST00000642864 / NM_001111125.3; = p.R595L on NM_015075.2) | Missense Mutation (SNP) | VAF 100/173 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KCNH2 | c.3395C>G p.P1132R | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- KCNS2 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1B | c.4718G>C p.S1573T (on ENST00000377086 / NM_001365952.1; = p.S1527T on NM_015074.3) | Missense Mutation (SNP) | VAF 35/478 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- KIF5C | c.1496A>G p.D499G | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- KLK7 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- KNDC1 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- LHX1 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX9 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 364/695 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRP1B | c.8915G>T p.C2972F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1B | c.4957G>C p.G1653R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LRRC25 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LYSMD1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1B | c.6323A>G p.E2108G | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- MESP2 | c.882G>A p.W294* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- MINDY4B | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MLPH | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MROH9 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- MTNR1B | c.348C>G p.S116R | Missense Mutation (SNP) | VAF 157/396 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYRFL | c.2161G>C p.V721L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAALADL2 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- NBPF15 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 8/494 reads (2%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, mutect2
- NFATC1 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 128/268 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRX1 | c.993C>G p.C331W | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NTRK3 | c.2038C>A p.L680M | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1C1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- OR2T1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR2W3 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR5D13 | c.876C>A p.Y292* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- OSR1 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OTOP1 | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PCDH17 | c.2870A>T p.Q957L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PCDHA6 | c.1159T>A p.C387S | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHGA2 | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLR3B | c.2566A>T p.I856L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R2C | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRAMEF19 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 52/748 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.259); called by muse, mutect2
- PRDM9 | c.2561A>T p.H854L | Missense Mutation (SNP) | VAF 73/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRUNE2 | c.8581G>T p.G2861C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PTGES3L-AARSD1 | c.1121G>T p.G374V (on ENST00000421990 / NM_001136042.2; = p.G356V on NM_025267.3) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD21L1 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- RAD50 | c.2528_2532del p.S843* | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- RAPGEF4 | c.444+8C>A | Splice Region (SNP) | VAF 70/347 reads (20%) | called by muse, mutect2, varscan2
- REG1A | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.6302G>T p.G2101V | Missense Mutation (SNP) | VAF 125/558 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RELN | c.4553G>T p.G1518V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RFX8 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPS19BP1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SAG | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16A | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SELENON | c.1134_1140del p.I378Mfs*? | Frame Shift Del (DEL) | VAF 87/324 reads (27%) | called by mutect2, pindel, varscan2
- SI | c.1540C>A p.Q514K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC15A4 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- SLC25A10 | c.51del p.C18Afs*23 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SLC28A2 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC9A3 | c.1922C>A p.T641K | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SLITRK5 | c.1374C>A p.N458K | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SP9 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPATA24 | c.352A>T p.S118C | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- STRIP1 | c.2222A>T p.Q741L | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- SUPT7L | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SVEP1 | c.7775C>A p.A2592D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 9/33 reads (27%) | called by pindel, varscan2*
- TCP11 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNR | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TPK1 | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- TRPV5 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.76928T>A p.V25643D (on ENST00000591111; = p.V18219D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/176 reads (6%) | PolyPhen possibly damaging (0.466); called by muse, mutect2
- UNC119 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- USP38 | c.3041T>A p.F1014Y | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.334); called by muse, mutect2
- VWA2 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR88 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WIZ | c.2417-2A>T p.X806_splice (on ENST00000673675 / NM_001371589.1; = p.X69_splice on NM_021241.3) | Splice Site (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- ZNF43 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF521 | c.3928A>G p.S1310G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF804A | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ZSCAN20 | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ADCY7 | c.1224C>T p.A408= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs758932458; called by muse, mutect2, varscan2
- ADD1 | c.567C>T p.Y189= | Silent (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- ADK | c.393G>A p.E131= (on ENST00000286621; = p.E114= on NM_001123.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- AJAP1 | c.1032G>T p.L344= | Silent (SNP) | VAF 185/555 reads (33%) | called by muse, mutect2, varscan2
- ATP2A1 | c.2847T>C p.Y949= | Silent (SNP) | VAF 122/649 reads (19%) | called by muse, mutect2, varscan2
- C21orf58 | c.573G>T p.P191= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs766961178, COSV99387943; called by muse, mutect2, varscan2
- C8A | c.90G>A p.R30= | Silent (SNP) | VAF 59/316 reads (19%) | catalogued as COSV63483484; called by muse, mutect2, varscan2
- CACNA1F | c.3042C>T p.F1014= | Silent (SNP) | VAF 40/383 reads (10%) | catalogued as COSV59903383; called by muse, mutect2, varscan2
- CAMK2B | c.1731T>A p.V577= | Silent (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- CCT8L2 | c.165C>A p.G55= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs1318596008; called by muse, mutect2
- CHD1 | c.282G>T p.L94= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- CTAGE15 | c.1233G>A p.E411= | Silent (SNP) | VAF 38/235 reads (16%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.1626C>A p.P542= | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- DIO3 | c.231G>T p.R77= | Silent (SNP) | VAF 63/287 reads (22%) | called by muse, mutect2, varscan2
- DNAH10 | c.5031G>A p.A1677= (on ENST00000409039; = p.A1616= on NM_207437.3) | Silent (SNP) | VAF 45/340 reads (13%) | catalogued as rs984373122, COSV68993401; called by muse, mutect2, varscan2
- DUSP10 | c.294C>T p.A98= | Silent (SNP) | VAF 22/395 reads (6%) | catalogued as rs770023650; called by muse, mutect2
- DYRK3 | c.861C>G p.A287= | Silent (SNP) | VAF 108/202 reads (53%) | called by muse, mutect2, varscan2
- FAM110A | c.801C>T p.G267= | Silent (SNP) | VAF 110/430 reads (26%) | catalogued as rs1220405799, COSV55726821; called by muse, mutect2, varscan2
- G6PC2 | c.918C>T p.L306= | Silent (SNP) | VAF 48/259 reads (19%) | called by muse, mutect2, varscan2
- GALNTL5 | c.402G>A p.P134= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as rs766808347, COSV67179626; called by muse, mutect2
- GFRA1 | c.964C>T p.L322= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- GPATCH3 | c.1338C>T p.H446= | Silent (SNP) | VAF 63/234 reads (27%) | called by muse, mutect2, varscan2
- GREB1 | c.3312G>T p.L1104= | Silent (SNP) | VAF 26/124 reads (21%) | called by muse, mutect2, varscan2
- HCFC1 | c.2976C>T p.A992= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as rs374301198; called by muse, mutect2, varscan2
- HES2 | c.369G>T p.A123= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- HMCN1 | c.10905G>T p.R3635= | Silent (SNP) | VAF 44/312 reads (14%) | called by muse, mutect2, varscan2
- HMCN2 | c.13026C>A p.P4342= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- HSPA12A | c.1479G>T p.A493= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs782001720; called by muse, mutect2, varscan2
- INPP5B | c.1350G>T p.G450= (on ENST00000373023; = p.G370= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs906358605; called by muse, mutect2, varscan2
- ITGAM | c.2178A>T p.P726= (on ENST00000648685 / NM_001145808.2; = p.P725= on NM_000632.4) | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- JPH2 | c.672C>T p.G224= | Silent (SNP) | VAF 200/516 reads (39%) | catalogued as COSV65904362; called by muse, mutect2, varscan2
- KRTAP24-1 | c.303C>A p.G101= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- LINGO2 | c.609C>A p.L203= | Silent (SNP) | VAF 79/148 reads (53%) | catalogued as COSV100430450; called by muse, mutect2, varscan2
- LPAR3 | c.615G>T p.V205= | Silent (SNP) | VAF 64/285 reads (22%) | called by muse, mutect2, varscan2
- LRFN1 | c.1905G>C p.P635= | Silent (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- MAGEB2 | c.222G>T p.A74= | Silent (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- MBL2 | c.570G>A p.K190= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- MMP17 | c.441G>T p.R147= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV62178950; called by muse, varscan2
- MS4A5 | c.214T>C p.L72= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV55741178; called by muse, mutect2, varscan2
- MUC5AC | c.16227G>T p.P5409= | Silent (SNP) | VAF 96/259 reads (37%) | called by muse, mutect2, varscan2
- NPRL3 | c.1656G>A p.V552= (on ENST00000611875 / NM_001077350.3; = p.V527= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 131/307 reads (43%) | called by muse, mutect2, varscan2
- NR0B1 | c.1062C>A p.S354= | Silent (SNP) | VAF 83/189 reads (44%) | catalogued as rs371576376, COSV100973555, COSV66764454; called by muse, mutect2, varscan2
- OPN1LW | c.228G>A p.A76= | Silent (SNP) | VAF 18/538 reads (3%) | catalogued as rs373658326; called by muse, mutect2
- OR2AK2 | c.741G>T p.V247= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- OR51E2 | c.156C>A p.R52= | Silent (SNP) | VAF 72/196 reads (37%) | called by muse, mutect2, varscan2
- PAPPA2 | c.120G>A p.L40= | Silent (SNP) | VAF 128/385 reads (33%) | catalogued as COSV62777504; called by muse, mutect2, varscan2
- PCDHA4 | c.1851C>T p.G617= | Silent (SNP) | VAF 79/437 reads (18%) | catalogued as rs370669259; called by muse, mutect2, varscan2
- PCDHB9 | c.969C>T p.D323= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs782033630, COSV53383386; called by muse, mutect2, varscan2
- PDILT | c.243G>A p.E81= | Silent (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- PLXNA1 | c.4224C>G p.L1408= | Silent (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- PPP1R17 | c.378C>A p.P126= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- PROCR | c.702T>A p.G234= | Silent (SNP) | VAF 251/699 reads (36%) | called by muse, mutect2, varscan2
- PTPRR | c.1245T>C p.H415= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs778501390; called by muse, mutect2, varscan2
- PXDNL | c.2451A>T p.T817= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as rs773870330; called by muse, mutect2, varscan2
- RPL10L | c.174G>A p.E58= | Silent (SNP) | VAF 89/439 reads (20%) | catalogued as rs1022379900; called by muse, mutect2, varscan2
- RPS19BP1 | c.9C>T p.A3= | Silent (SNP) | VAF 77/186 reads (41%) | called by muse, mutect2, varscan2
- RYR2 | c.9234C>A p.G3078= | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- SERPINA3 | c.441C>A p.L147= | Silent (SNP) | VAF 69/358 reads (19%) | catalogued as COSV67586182; called by muse, mutect2, varscan2
- SETBP1 | c.867G>T p.V289= | Silent (SNP) | VAF 118/267 reads (44%) | called by muse, mutect2, varscan2
- SHISA6 | c.114C>T p.G38= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1333076237; called by muse, mutect2, varscan2
- SLITRK1 | c.705G>T p.L235= | Silent (SNP) | VAF 40/263 reads (15%) | called by muse, mutect2, varscan2
- TBX5 | c.942C>A p.P314= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as COSV100090643; called by muse, mutect2, varscan2
- TEX55 | c.894T>A p.V298= | Silent (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- TICRR | c.264C>A p.A88= | Silent (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2, varscan2
- TMEM11 | c.225C>T p.I75= | Silent (SNP) | VAF 58/193 reads (30%) | called by muse, mutect2, varscan2
- TMEM121 | c.306C>T p.R102= | Silent (SNP) | VAF 26/504 reads (5%) | catalogued as COSV66796151; called by muse, mutect2
- TMEM121B | c.1656C>T p.S552= | Silent (SNP) | VAF 60/654 reads (9%) | called by muse, mutect2
- UNC93A | c.141T>C p.Y47= | Silent (SNP) | VAF 56/308 reads (18%) | called by muse, mutect2, varscan2
- WDPCP | c.1998A>G p.S666= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- WFS1 | c.1863G>T p.V621= | Silent (SNP) | VAF 27/256 reads (11%) | called by muse, mutect2, varscan2
- ZNF717 | c.1656A>T p.V552= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2
- ZSWIM8 | c.1050G>A p.L350= | Silent (SNP) | VAF 22/208 reads (11%) | called by muse, varscan2
- AC027031.1 | n.284C>A | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- AC079154.1 | n.839C>A | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- ADD1 | c.885+10C>G | Intron (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- ADGB | c.4818+5466C>A | Intron (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- AP000679.1 | n.603G>T | RNA (SNP) | VAF 44/267 reads (16%) | catalogued as rs1172603911; called by muse, mutect2, varscan2
- ATP1A2 | c.2840+18T>A | Intron (SNP) | VAF 212/543 reads (39%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700684 G>A | 3'Flank (SNP) | VAF 44/1793 reads (2%) | called by muse, mutect2
- CACNG7 | c.-2G>T | 5'UTR (SNP) | VAF 76/247 reads (31%) | catalogued as COSV99712280; called by muse, mutect2, varscan2
- CACNG7 | c.-1G>T | 5'UTR (SNP) | VAF 75/249 reads (30%) | called by muse, mutect2, varscan2
- CLK2P1 | n.487C>A | RNA (SNP) | VAF 61/360 reads (17%) | called by muse, mutect2, varscan2
- DERL3 | c.327+37G>A | Intron (SNP) | VAF 127/380 reads (33%) | called by muse, mutect2, varscan2
- DNM1L | c.251-630T>G | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ENPEP | c.2225+10A>G | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- GALNT2 | n.74C>A | RNA (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- GALNT2 | n.75C>A | RNA (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- IZUMO3 | c.-233G>T | 5'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- LBP | c.-1G>A | 5'UTR (SNP) | VAF 45/251 reads (18%) | called by muse, mutect2, varscan2
- LGMN | c.*159G>T | 3'UTR (SNP) | VAF 86/240 reads (36%) | called by muse, mutect2, varscan2
- LINC02145 | n.450G>A | RNA (SNP) | VAF 8/68 reads (12%) | catalogued as rs369179788; called by muse, mutect2, varscan2
- MROH8 | c.-306del | 5'UTR (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel
- NDUFS2 | c.-14G>A | 5'UTR (SNP) | VAF 248/675 reads (37%) | catalogued as rs1252585066; called by muse, mutect2, varscan2
- OLAH | c.164-4789C>G | Intron (SNP) | VAF 28/122 reads (23%) | catalogued as COSV65491924; called by muse, mutect2, varscan2
- PAMR1 | c.821-10214G>T | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1392+18C>T | Intron (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PPARA | c.-29G>T | 5'UTR (SNP) | VAF 108/287 reads (38%) | called by muse, mutect2, varscan2
- PRRT1 | c.*105C>A | 3'UTR (SNP) | VAF 110/400 reads (28%) | called by muse, mutect2, varscan2
- PTHLH | c.-22-34A>T | Intron (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.444+9T>C | Intron (SNP) | VAF 70/348 reads (20%) | called by muse, mutect2, varscan2
- SBF1 | c.3827-45C>G | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as COSV62369090; called by muse, mutect2, varscan2
- SEPTIN9 | c.76+13104C>T | Intron (SNP) | VAF 108/298 reads (36%) | catalogued as rs778765666; called by muse, varscan2
- SNX6 | c.43-42C>G | Intron (SNP) | VAF 24/106 reads (23%) | catalogued as rs1445881615; called by muse, mutect2, varscan2
- SOX2 | c.*5C>A | 3'UTR (SNP) | VAF 80/518 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.1022G>T | RNA (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- SUMF2 | c.396+122A>T | Intron (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2
- TLCD3B | c.540+60C>A | Intron (SNP) | VAF 62/505 reads (12%) | called by muse, mutect2, varscan2
- TLN2 | c.5736+37C>T | Intron (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2
- WIPF1 | c.1129+54C>A | Intron (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- XIRP2 | c.*415G>T | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776410 C>T | 5'Flank (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
